Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAOH, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AAOH-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Mixed germ cell tumor 9085/3
Site: Testis NOS C62.9

W 5/21/14

SURGICAL PATH []

Order Dr:

Order Clinic:

Order Dx: OPS

Specimen Source: L TESTICLE

CASE NO.:

GROSS EXAM DATE:

PHYSICIAN & PAGER #:

-- CONCLUSION/DIAGNOSTIC CODE -----

NON-ROUTINE

-- REPORT -----

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. MIXED GERM CELL TUMOR (6.5 CM) COMPOSED OF EMBRYONAL CARCINOMA (60%), YOLK SAC TUMOR (30%) AND CHORIOCARCINOMA (20%), left testicle, procedure not stated. (see note)
2. NO LYMPHOVASCULAR OR EPIDIDYMIS INVASION NOTED.
3. SEMINIFEROUS TUBULE ATROPHY WITHOUT EVIDENCE OF SPERMATOGENESIS.
4. INTRATUBULAR GERM CELL NEOPLASIA.
5. pT1NXMX.

Note: All three components were CAM5.2 and AE1/AE3 keratin positive. The embryonal carcinoma is CD30 positive, yolk sac tumor is AFP positive and the choriocarcinoma is HCG positive. These findings confirm the above diagnosis.

GROSS DESCRIPTION:

The specimen was received fresh in one part labeled with the patient's name, and left testicle. It consists of 108.2 grams orchietomy specimen including 6.5 x 5 x 4.5 cm of testes, 3.5 x 1.5 cm epididymis and 9 cm in length and 1.2 cm in diameter spermatic cord. The tunica vaginalis was smooth, glistening and tan-white. Sectioning through the specimen shows entire testicle to be replaced by a tumor that is tan-white, variegated, fleshy and well-circumscribed with focal areas of hemorrhage. There was no gross involvement of tunica albuginea or impingement on the epididymis. No normal testicular tissue was identified. Spermatic cord consists of vas deferens, arteries and veins and is unremarkable. Representative sections are submitted as follows:

[page 2 of 3]
-- REPORT --

Cassette 1: Spermatic cord, surgical margin.
Cassette 2: Spermatic cord, mid.
Cassette 3: Distal spermatic cord.
Cassette 4: Tumor with tunica vaginal list.
Cassettes 5 and 6: Tumor with epididymis.
Cassettes 7 and 8: Representative sections of the tumor.
Cassette 9: Tumor with tunica vaginalis.
T9.

Per TSS dx discrepancy form,
TCGA tumor is yolk sac 30%,
embryonal 70%

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS):

TSS Identifier:

TSS Unique Patient Identifier:

Completed By (Interviewer Name on OpenClinica):

Completed Date:

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Embryonal Carcinoma 60%, Yolk Sac Tumor 30%, Choriocarcinoma 20%	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Yolk Sac Tumor 30%, Embryonal Carcinoma 70%	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	histologic heterogeneity characteristic of mixed germ cell tumors Error in calculation of combined total percentages in the original pathology report noted.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 42c9c995-9117-4f54-bab2-04d2b92a9f79 (TCGA-XE-AAOH-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).